Somatic mutation profile of tumor specimen TCGA-18-3406-01A (aliquot TCGA-18-3406-01A-01D-0983-08) from TCGA case TCGA-18-3406, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.0 years (24,477 days).
Specimen TCGA-18-3406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1c1c9bf-fdb8-4bfd-b7ce-806eb2c97feb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3406-11A (Solid Tissue Normal), aliquot TCGA-18-3406-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e590e3d3-cec9-470c-8050-aaf7a3a6295c

The open-access MAF lists 236 somatic variants for this specimen: 170 protein-altering or splice-affecting, 58 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 58, Nonsense Mutation 14, RNA 5, Splice Region 3, Splice Site 3, Intron 2, Frame Shift Del 2, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.647T>A p.V216E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520004, COSV52676908, COSV52856938, COSV52866969, COSV53036902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBGCP6 | c.2215C>T p.R739* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as rs724159975, CM1411966, COSV50548883; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.544C>G p.L182V (on ENST00000614293; = p.L152V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV55802169; called by muse, varscan2
- ABCC1 | c.3720C>T p.V1240= | Splice Region (SNP) | VAF 5/40 reads (13%) | catalogued as COSV60686970; called by mutect2, varscan2
- ADAM20 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as COSV56455148; called by muse, mutect2, varscan2
- ADAMTS19 | c.2509C>A p.L837I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV50752158, COSV50758324; called by muse, mutect2, varscan2
- ADCY4 | c.2842G>C p.D948H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100156748, COSV60254754; called by muse, mutect2, varscan2
- ADGRF5 | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51934689; called by muse, mutect2, varscan2
- ADGRG6 | c.3637C>T p.Q1213* | Nonsense Mutation (SNP) | VAF 32/312 reads (10%) | catalogued as rs1053617641, COSV51593426; called by muse, mutect2, varscan2
- AKAP9 | c.7795C>T p.Q2599* (on ENST00000359028; = p.Q2575* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as rs770355887, COSV62347860; called by muse, mutect2, varscan2
- AMER1 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1417833376, COSV57661613; called by muse, mutect2, varscan2
- ANKMY2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61011854; called by muse, mutect2, varscan2
- ARHGEF12 | c.4354C>G p.H1452D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV63105123; called by muse, mutect2, varscan2
- ASH1L | c.7514A>G p.Y2505C (on ENST00000368346 / NM_001366177.2; = p.Y2500C on NM_018489.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs776234558, COSV64208630; called by muse, mutect2, varscan2
- ASH1L | c.5809G>A p.E1937K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); catalogued as rs142217207; called by muse, mutect2, varscan2
- ATN1 | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.222); catalogued as COSV100755823, COSV63110550; called by muse, mutect2
- ATRX | c.4834C>G p.L1612V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64877522; called by muse, mutect2, varscan2
- BAIAP3 | c.3014C>T p.T1005I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV50104091; called by muse, varscan2
- BDP1 | c.6022G>T p.V2008L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV100703259, COSV62431760; called by muse, mutect2, varscan2
- BRSK1 | c.856C>T p.L286= | Splice Region (SNP) | VAF 109/519 reads (21%) | catalogued as rs549853359, COSV58667173, COSV58669453; called by muse, mutect2, varscan2
- BRWD3 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV64748961, COSV64754484; called by muse, mutect2, varscan2
- C10orf88 | c.290G>C p.R97T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64404011; called by muse, mutect2
- C7 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100495553, COSV57477481, COSV57482578; called by muse, mutect2, varscan2
- CA7 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.827); catalogued as COSV58156581; called by muse, mutect2, varscan2
- CARD6 | c.879G>C p.L293F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54565959, COSV54566281; called by muse, mutect2, varscan2
- CASP9 | c.135G>T p.R45= | Splice Region (SNP) | VAF 20/75 reads (27%) | catalogued as COSV61601581; called by muse, mutect2, varscan2
- CCAR1 | c.1134G>C p.M378I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV56270205; called by muse, mutect2, varscan2
- CCDC141 | c.3924G>C p.K1308N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs910795143, COSV55374778; called by muse, mutect2, varscan2
- CLDN8 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54526083, COSV54526345; called by muse, mutect2, varscan2
- CNGA4 | c.1122T>A p.Y374* | Nonsense Mutation (SNP) | VAF 66/206 reads (32%) | catalogued as COSV66006134; called by muse, mutect2, varscan2
- CNTNAP4 | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV56683207; called by muse, mutect2, varscan2
- CPSF2 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV54098653; called by muse, mutect2, varscan2
- CPTP | c.645G>C p.*215Yext*44 | Nonstop Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV59563694; called by muse, mutect2, varscan2
- CTNNA2 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1328323453, COSV63571963; called by muse, mutect2, varscan2
- CWF19L2 | c.1418A>G p.K473R | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56513392; called by muse, mutect2, varscan2
- CYLC1 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61412619; called by muse, mutect2, varscan2
- CYP26B1 | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV50012134; called by mutect2, varscan2
- DCHS1 | c.9728G>A p.G3243D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs778012430, COSV54998055; called by muse, mutect2, varscan2
- DNAH12 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1474682409, COSV60857214; called by muse, mutect2
- DNTTIP2 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV63284122; called by muse, mutect2, varscan2
- E2F7 | c.2650G>A p.V884I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV59740536; called by muse, mutect2, varscan2
- F8 | c.1538-1G>A p.X513_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as CS034840, CS080684, COSV64274152; called by muse, mutect2, varscan2
- FAM111B | c.2042T>C p.I681T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1469534885, COSV59112146; called by muse, mutect2, varscan2
- FAT3 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53119144, COSV53144223; called by muse, mutect2, varscan2
- FBN1 | c.2513T>C p.L838S | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CD075391, CM098666, COSV57318610; called by muse, mutect2
- FBXW7 | c.1754G>C p.S585T (on ENST00000281708 / NM_001349798.2; = p.S505T on NM_018315.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV55921131; called by muse, mutect2
- FEM1B | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV60988183; called by muse, mutect2, varscan2
- FLG2 | c.4430G>A p.R1477K | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV66169212; called by muse, mutect2, varscan2
- FN1 | c.4070G>A p.G1357D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV60554482; called by muse, mutect2, varscan2
- GLI1 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57362943; called by muse, mutect2, varscan2
- GMCL1 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV57001905; called by muse, mutect2
- GPR85 | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV51782492, COSV51783766; called by muse, mutect2, varscan2
- GRIP2 | c.2380A>T p.I794F (on ENST00000619221; = p.I697F on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV56121912; called by muse, mutect2, varscan2
- H4C8 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs766453964, COSV56805105; called by muse, mutect2, varscan2
- H4C9 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); catalogued as COSV100574920, COSV62889876; called by muse, mutect2, varscan2
- HAO1 | c.956G>T p.W319L | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101113153; called by muse, mutect2, varscan2
- HIPK1 | c.920A>T p.K307M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65784866; called by muse, mutect2, varscan2
- HMMR | c.1655G>C p.R552T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV62374610; called by muse, mutect2, varscan2
- HYAL1 | c.972G>A p.W324* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs1310645828, COSV56498071; called by muse, mutect2, varscan2
- IGKV1-5 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs774100906; called by muse, mutect2, varscan2
- IMPG2 | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51979315; called by muse, mutect2, varscan2
- IPMK | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as COSV64243845; called by muse, mutect2, varscan2
- KASH5 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as rs926786809, COSV71358043; called by muse, mutect2
- KBTBD12 | c.1463C>G p.A488G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV59679574; called by muse, mutect2
- KCNH3 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV57791096; called by muse, mutect2, varscan2
- KIF6 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 103/168 reads (61%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1267886000, COSV54679707; called by muse, mutect2, varscan2
- KIFBP | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.492); catalogued as rs770724316, COSV62831793, COSV62832648; called by muse, mutect2, varscan2
- KRTAP5-2 | c.353G>C p.C118S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV69014996; called by muse, mutect2, varscan2
- LAMA4 | c.1017C>G p.I339M (on ENST00000230538 / NM_001105206.3; = p.I332M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV57898085; called by muse, mutect2, varscan2
- LILRA2 | c.1233C>A p.D411E | Missense Mutation (SNP) | VAF 129/295 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs200605637, COSV52192347; called by muse, mutect2, varscan2
- LRFN5 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as COSV53258897, COSV53269538, COSV99984233; called by muse, mutect2, varscan2
- LRP6 | c.4360G>A p.G1454R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV53788270; called by muse, varscan2
- MAP1S | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as COSV60722900; called by muse, mutect2, varscan2
- MCHR2 | c.587+2T>G p.X196_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | catalogued as COSV56003771; called by muse, mutect2, varscan2
- MGAT5B | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56930123; called by muse, mutect2, varscan2
- MKI67 | c.6589T>G p.L2197V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV64074748; called by muse, mutect2, varscan2
- MMS22L | c.1933C>T p.H645Y | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV51521724; called by muse, mutect2, varscan2
- MRPS27 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54651052; called by muse, mutect2, varscan2
- MUC16 | c.14831A>G p.D4944G | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1210473504, COSV67470328; called by muse, mutect2, varscan2
- MUC17 | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV60290474; called by muse, mutect2
- MYCBP2 | c.937A>T p.M313L (on ENST00000357337; = p.M351L on NM_015057.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV62021621; called by muse, mutect2, varscan2
- MYH1 | c.2872A>T p.I958F | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99875202; called by muse, mutect2, varscan2
- MYH2 | c.2989A>G p.K997E | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV55439560; called by muse, mutect2, varscan2
- MYH7 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1036184671, COSV62519869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.5804G>T p.S1935I | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV67966108; called by muse, mutect2, varscan2
- MYH8 | c.1323G>T p.W441C | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67960594, COSV67966111; called by muse, mutect2, varscan2
- N4BP2 | c.1827A>T p.R609S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV54702533; called by muse, mutect2, varscan2
- NELL1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.949); catalogued as COSV54271106; called by muse, mutect2, varscan2
- NLGN4X | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV52020773; called by muse, mutect2, varscan2
- NOD2 | c.1556A>C p.Q519P | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs368316739; called by muse, mutect2, varscan2
- NRK | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54597986; called by muse, mutect2, varscan2
- NUMA1 | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as rs1342065233, COSV61186157; called by muse, mutect2, varscan2
- OR51B2 | c.907C>A p.R303S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV60916873; called by muse, mutect2, varscan2
- OR51Q1 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.133); catalogued as rs753723832, COSV56179386; called by muse, mutect2, varscan2
- OR52E4 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57624972; called by muse, mutect2
- OR5K3 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV67350166; called by muse, mutect2, varscan2
- OR8A1 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as COSV52508857; called by muse, mutect2, varscan2
- OR8G1 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.443); catalogued as COSV100422285; called by muse, mutect2, varscan2
- PARD3B | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 10/189 reads (5%) | catalogued as COSV62513651; called by muse, mutect2
- PDS5A | c.3923G>T p.G1308V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as COSV57826527; called by muse, mutect2, varscan2
- PDZRN3 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228311885, COSV55202140; called by muse, mutect2, varscan2
- PHC3 | c.1631C>T p.S544L (on ENST00000494943 / NM_001308116.2; = p.S556L on NM_024947.4) | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1314074249, COSV71948785; called by muse, mutect2, varscan2
- PHKB | c.3029T>A p.L1010Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54522972; called by muse, mutect2, varscan2
- PHRF1 | c.4865C>G p.A1622G (on ENST00000264555 / NM_001286581.2; = p.A1621G on NM_020901.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52756665, COSV99199700; called by muse, varscan2
- PIK3AP1 | c.80T>A p.L27Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59533175; called by muse, mutect2, varscan2
- PIKFYVE | c.4211C>T p.P1404L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV52242105; called by muse, mutect2, varscan2
- PLEKHH2 | c.3942-1G>A p.X1314_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56755126; called by mutect2, varscan2
- PPDPF | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV64547329; called by muse, mutect2, varscan2
- PPIP5K2 | c.2717T>C p.L906S | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV58602079, COSV58606036; called by muse, mutect2
- PRH2 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.592); catalogued as COSV67171685; called by muse, mutect2, varscan2
- PROX2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs367763340, COSV71520069; called by muse, mutect2, varscan2
- PTPN14 | c.2593C>A p.L865M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100872306, COSV65284633; called by muse, varscan2
- QRFPR | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs200911686, COSV57677486; called by muse, varscan2
- QRICH1 | c.1167G>C p.M389I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV62615826; called by muse, mutect2, varscan2
- REEP2 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV54735118; called by mutect2, varscan2
- RGL1 | c.1886C>T p.S629L (on ENST00000360851 / NM_001297672.2; = p.S664L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs781195114, COSV58986592; called by muse, mutect2, varscan2
- RGL2 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65842346; called by muse, varscan2
- ROS1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs745980825, COSV63856085; called by muse, mutect2, varscan2
- RP1 | c.6323T>A p.I2108N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV55118129; called by muse, mutect2, varscan2
- RPS6 | c.744G>T p.Q248H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV59548023; called by muse, mutect2, varscan2
- RTL1 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.159); catalogued as COSV66016922; called by muse, mutect2, varscan2
- RYR2 | c.8642A>G p.E2881G | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63688692; called by muse, mutect2, varscan2
- SATB2 | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559136030, COSV53483172, COSV53488467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3E | c.2071C>T p.H691Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV57092661; called by muse, mutect2, varscan2
- SI | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs148454534, COSV100015176; called by muse, mutect2, varscan2
- SIGLEC12 | c.433C>A p.Q145K (on ENST00000291707 / NM_053003.4; = p.Q27K on NM_033329.2) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV52461974; called by muse, mutect2, varscan2
- SLC22A23 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV66677822; called by muse, mutect2, varscan2
- SLC23A2 | c.483G>T p.R161S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57775086; called by muse, mutect2, varscan2
- SLC25A18 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs747077686, COSV59408495; called by muse, mutect2, varscan2
- SLC30A8 | c.1103G>A p.C368Y | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1356637421, COSV69971155; called by muse, mutect2, varscan2
- SLC7A2 | c.1034C>G p.S345C (on ENST00000494857 / NM_001370338.1; = p.S385C on NM_003046.6) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50255166; called by muse, mutect2, varscan2
- SLC7A5 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV55364777; called by muse, mutect2
- SLC9A9 | c.828del p.N277Ifs*23 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | catalogued as COSV57220719; called by mutect2, pindel, varscan2
- SMAP2 | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); catalogued as rs771321571, COSV65532572; called by muse, mutect2, varscan2
- SMOC2 | c.1257C>G p.D419E (on ENST00000356284 / NM_001166412.2; = p.D430E on NM_022138.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62438807; called by muse, mutect2, varscan2
- SNX25 | c.1631C>G p.T544S | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV53014887; called by muse, mutect2, varscan2
- SORL1 | c.3235C>G p.L1079V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); catalogued as rs1011398873, COSV52755510; called by muse, mutect2, varscan2
- STIL | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54550737; called by mutect2, varscan2
- STYXL1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV50389326; called by muse, mutect2, varscan2
- TBL3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.912); catalogued as rs541759826, COSV60341577; called by mutect2, varscan2
- TBX22 | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64786243, COSV64787629; called by muse, mutect2
- TDRD5 | c.1665A>T p.E555D | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV54243911; called by muse, mutect2, varscan2
- TESPA1 | c.1301G>C p.R434T (on ENST00000316577 / NM_001098815.3; = p.R296T on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); catalogued as COSV57259200; called by muse, mutect2, varscan2
- TIGAR | c.365G>C p.G122A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as COSV51628102; called by muse, mutect2, varscan2
- TMEM214 | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV53192874; called by muse, mutect2, varscan2
- TMEM242 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV65654172; called by muse, mutect2, varscan2
- TNS2 | c.394G>C p.D132H (on ENST00000314250 / NM_170754.4; = p.D142H on NM_015319.2) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1209331655, COSV58578127; called by muse, mutect2, varscan2
- TOLLIP | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143130045; called by muse, mutect2, varscan2
- TPH2 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV61592310, COSV61593282; called by muse, mutect2, varscan2
- TPP2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV65752989; called by muse, mutect2, varscan2
- TRIM37 | c.1796G>C p.R599T | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV51884625; called by muse, varscan2
- TSPAN31 | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV57276339; called by mutect2, varscan2
- TXNDC16 | c.1885C>A p.Q629K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.042); catalogued as COSV55984970; called by muse, mutect2, varscan2
- USH2A | c.7881C>G p.I2627M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56378138; called by muse, mutect2, varscan2
- USP29 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54143328; called by muse, mutect2, varscan2
- USP36 | c.400A>G p.N134D | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61751942; called by muse, mutect2, varscan2
- VPS35 | c.838A>T p.N280Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV54479110; called by muse, mutect2, varscan2
- WDR17 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54575293, COSV54583940, COSV54586090; called by muse, mutect2, varscan2
- XAGE3 | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV60569351; called by muse, mutect2, varscan2
- ZDHHC5 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1481014369, COSV54707035, COSV99762183; called by muse, mutect2, varscan2
- ZFHX4 | c.7625C>G p.P2542R | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50893025, COSV99268102; called by muse, mutect2, varscan2
- ZNF41 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV57442928; called by mutect2, varscan2
- ZNF41 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57442948; called by mutect2, varscan2
- ZNF564 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as rs1286121601, COSV59435132; called by muse, mutect2, varscan2
- ZNF614 | c.396G>C p.L132F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as COSV54546228, COSV54546547; called by muse, mutect2, varscan2
- ZNF765 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV67182669; called by muse, mutect2, varscan2
- C18orf54 | c.193_199del p.Y65Vfs*52 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- IGKV1D-8 | c.227T>C p.L76S | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SLC6A18 | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- ADAMTS12 | c.4716C>A p.P1572= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV100710440, COSV61265682; called by muse, mutect2, varscan2
- ADCY5 | c.2058C>A p.G686= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV59198665; called by muse, mutect2, varscan2
- ARID1B | c.6033G>T p.T2011= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV51664019; called by muse, mutect2, varscan2
- BDP1 | c.7281A>C p.G2427= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV62431765; called by muse, mutect2, varscan2
- BHMT | c.864C>A p.A288= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV57154561; called by muse, mutect2, varscan2
- BIRC6 | c.14163A>T p.T4721= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as COSV70199973; called by muse, mutect2, varscan2
- CHD7 | c.3261T>A p.I1087= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV71111293; called by muse, mutect2, varscan2
- CYTH4 | c.927G>A p.S309= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs750313095, COSV50632860; called by muse, mutect2
- DLGAP3 | c.2619G>A p.A873= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1345564244, COSV52392961; called by muse, mutect2, varscan2
- FCRL5 | c.2343G>A p.L781= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs1297864951, COSV62511267, COSV62515188; called by muse, mutect2, varscan2
- GBF1 | c.3069C>A p.I1023= (on ENST00000369983 / NM_001377137.1; = p.I1022= on NM_004193.3) | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV64145413; called by muse, mutect2, varscan2
- GRM3 | c.2142C>T p.T714= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV64472719; called by muse, mutect2, varscan2
- IGHV3-72 | c.304C>T p.L102= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV70409630; called by muse, mutect2, varscan2
- ILDR1 | c.912T>A p.P304= (on ENST00000344209 / NM_001199799.2; = p.P260= on NM_175924.4) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV56550416; called by muse, mutect2, varscan2
- IMPA1 | c.825C>T p.D275= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV56271640; called by mutect2, varscan2
- KCNK10 | c.441C>T p.N147= | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV56645702; called by muse, mutect2, varscan2
- KLF3 | c.651C>T p.P217= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV54711021; called by muse, mutect2, varscan2
- KRTAP19-3 | c.93C>T p.S31= | Silent (SNP) | VAF 48/206 reads (23%) | catalogued as COSV61854766; called by muse, mutect2, varscan2
- LCMT2 | c.1386G>C p.L462= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs1214156336, COSV59790606; called by muse, mutect2, varscan2
- LGALS4 | c.369G>A p.E123= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV57043884; called by muse, mutect2, varscan2
- LRP10 | c.1857G>A p.K619= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62078357; called by muse, mutect2, varscan2
- LRP6 | c.3408G>A p.R1136= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs772100523, COSV53788276; called by muse, mutect2, varscan2
- MAEL | c.438C>A p.L146= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV63305215; called by muse, mutect2, varscan2
- MAS1 | c.364C>T p.L122= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as COSV53121290; called by muse, mutect2, varscan2
- MAST1 | c.1314C>T p.F438= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV52247922; called by muse, mutect2, varscan2
- MINAR1 | c.1593T>C p.S531= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV59583520; called by muse, mutect2, varscan2
- MMRN2 | c.1197G>A p.E399= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV64400699, COSV64400818; called by muse, mutect2, varscan2
- MTTP | c.264T>C p.N88= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV55506362; called by muse, mutect2
- MUC5B | c.7893A>T p.P2631= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs371333011, COSV71592357; called by muse, mutect2, varscan2
- NCOR2 | c.990C>A p.R330= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV62298870, COSV62306617; called by muse, mutect2, varscan2
- OR11H12 | c.561C>T p.N187= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs577907309; called by mutect2, varscan2
- OR51G2 | c.234C>T p.L78= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV58993226; called by muse, mutect2
- OR52E4 | c.516G>T p.G172= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV57624983, COSV57625862; called by muse, varscan2
- OR5F1 | c.600T>A p.S200= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV53546765; called by muse, mutect2, varscan2
- OR5T1 | c.729T>A p.A243= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as COSV57302955; called by muse, mutect2, varscan2
- OSBPL8 | c.1866A>T p.S622= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV53883406; called by muse, mutect2, varscan2
- PAQR8 | c.153C>T p.I51= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV62442736; called by muse, mutect2, varscan2
- PCDHGA9 | c.1539G>C p.V513= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV53960497; called by muse, mutect2, varscan2
- PCNX4 | c.1176C>T p.G392= (on ENST00000406854 / NM_001330177.2; = p.G158= on NM_022495.5) | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as COSV58304797; called by muse, mutect2, varscan2
- PKD1 | c.8937C>T p.F2979= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as CD012703, COSV51917483; called by muse, mutect2, varscan2
- PLIN4 | c.1467C>A p.S489= (on ENST00000301286; = p.S504= on NM_001367868.2) | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV56688736, COSV56692305; called by muse, mutect2, varscan2
- PRKD1 | c.1170G>A p.E390= | Silent (SNP) | VAF 42/214 reads (20%) | catalogued as COSV59571148; called by muse, mutect2, varscan2
- PTPRR | c.276G>T p.P92= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV51734090; called by muse, varscan2
- RGL3 | c.1161C>G p.L387= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as rs373924071, COSV63387141; called by muse, varscan2
- SBDS | c.633G>C p.L211= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV55887755; called by muse, mutect2, varscan2
- SEC23B | c.1851C>T p.S617= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52719857; called by muse, mutect2, varscan2
- SERPINI2 | c.105A>G p.Q35= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV52986487; called by muse, mutect2, varscan2
- SKIV2L | c.3495G>A p.L1165= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV61713825; called by muse, mutect2, varscan2
- SLC5A1 | c.558A>G p.A186= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV56685792; called by muse, mutect2, varscan2
- SLC6A18 | c.171C>T p.L57= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV57251653; called by mutect2, varscan2
- SLC8A1 | c.489A>G p.A163= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV60482382; called by muse, mutect2, varscan2
- SORCS1 | c.385C>A p.R129= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99544207; called by muse, mutect2, varscan2
- SPATA31E1 | c.2070T>C p.D690= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs1288043460, COSV57792171; called by muse, mutect2, varscan2
- TBX3 | c.1089G>A p.S363= (on ENST00000257566 / NM_016569.4; = p.S343= on NM_005996.4) | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs1367436140, CP995121, COSV57470444; called by muse, mutect2, varscan2
- TLCD5 | c.51C>T p.L17= (on ENST00000375095 / NM_001198671.2; = p.L39= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV58755118; called by muse, mutect2, varscan2
- TRHDE | c.2526C>A p.S842= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV53846697; called by muse, varscan2
- VWA5A | c.1233A>G p.R411= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV63707682; called by muse, mutect2
- ZNF714 | c.216G>A p.L72= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV52512385; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640959 A>G | 3'Flank (SNP) | VAF 6/37 reads (16%) | catalogued as rs1567607607, COSV51704929; called by mutect2, varscan2
- OR2W5 | n.928C>A | RNA (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- OR2W5 | n.929C>A | RNA (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1820C>T | RNA (SNP) | VAF 8/38 reads (21%) | catalogued as rs546377245, COSV59420915; called by mutect2, varscan2
- PIGK | c.987-7004del | Intron (DEL) | VAF 8/62 reads (13%) | called by pindel, varscan2
- SORBS2 | c.685-7486C>T | Intron (SNP) | VAF 24/98 reads (24%) | catalogued as rs369221375; called by muse, mutect2, varscan2
- SSPOP | n.2620G>A | RNA (SNP) | VAF 4/8 reads (50%) | catalogued as rs1176489080, COSV50487744; called by mutect2, varscan2
- TMEM183B | n.983G>C | RNA (SNP) | VAF 50/310 reads (16%) | called by muse, mutect2, varscan2
